Surgical pathology report (de-identified scan), TCGA case TCGA-AY-5543, project TCGA-COAD (Colon Adenocarcinoma), tissue source site UNC, specimen TCGA-AY-5543-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

A: Omentum, mass, excision

- Metastatic adenocarcinoma, consistent with colonic primary

B: Terminal ileum, appendix and right colon, right hemicolectomy

Tumor Histologic Type: Invasive moderately differentiated colorectal adenocarcinoma

Histologic Grade: 2

Tumor Location: Right colon

Depth of Invasion: Through muscularis propria into the subserosa, pericolic soft tissue

Lymphovascular Invasion: Not identified

Perineural Invasion: Not identified

Margins:

Proximal margin: Negative

Distal margin: Negative

Circumferential (radial) margin: Negative but close, <1.0 mm

Distance of carcinoma from closest margin (specify): <1.0 mm from serosal surface; 8.5 cm from proximal mucosal margin.

Regional Lymph Nodes:

Total number with metastasis: 1

Total number examined: 24

Additional pathologic findings: Appendix with follicular lymphoid hyperplasia and no tumor seen; tumor satellite nodule identified.

AJCC PATHOLOGIC TNM STAGE: pT3 pN1a

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

C: Liver mass, Segment 5, removal

- No evidence of metastatic disease.

- Benign liver with minimal steatosis and mild portal triaditis

D: Hernia sac, removal

- Benign fibrovascular and fibroadipose soft tissue, consistent with hernia sac, with focal foreign body giant cell reaction with associated polarizable foreign material; no evidence of metastatic disease.

Clinical History:

large mass in the ascending colon. Biopsy demonstrates invasive moderately differentiated adenocarcinoma. CT imaging confirms mass and evidence of metastatic disease.

Gross Description:

Received are four formalin-filled containers.

Container A:

SITE: "omentum"

METHOD: excision

MEASURE: 6.5 x 3.6 x 1.5 cm

COMMENT: yellow/tan fibroadipose tissue with a central firm hard mass; cut section demonstrates a white/yellow firm surface

BLOCK: A1, omental mass

Container B:

[page 2 of 3]
Specimen fixation: formalin

Parts of bowel received: terminal ileum, cecum and proximal ascending colon

Specimen length: 27.3 cm

Orientation: The specimen was received with a stitched end which appears to be the right ascending colon, inked blue. The distal ileum is inked black.

Tumor location: tumor is located just distal, but apparently involving the ileocecal valve

Gross appearance of tumor: distal to the ileocecal valve is a ulcerated mass with whorled edges, this mass is firm; proximal to this is the ileocecal valve and this also appears to be at least superficially studded with tumor

Tumor dimensions: 3.5 x 2.4 x 1.2 cm

Circumferential growth: 70%

Gross depth of invasion: the mass appears to grossly invade the subserosal soft tissues

Gross evidence of perforation through visceral peritoneum: no

Luminal obstruction: no

Bowel circumference at tumor site: 6.0 cm, 1.5 cm diameter at tumor site

Gross distance of tumor from margins: 9 cm from blue inked distal margin, 8.5 cm from black inked proximal margin

Lymph nodes: per block summary

Other remarkable findings: The rest of the colon and ileum are grossly unremarkable. Appendix is present with the specimen and is not grossly involved.

Tissue submitted for special investigation: tissue submitted to Tissue Procurement

Digital photograph taken: no

Block Summary:

(Inking: proximal ileal margin=black, distal right colonic margin with stitch=blue)

B1 - appendix, longitudinal section of tip, cross section of base

B2 - proximal (black inked) margin, en face

B3,B4 - distal (blue inked) margin, en face

B5 - section of mass

B6,B7 - additional section of mass, bisected

B8 - mass in relation to pericolic fat

B9 - section of ileocecal valve

B10 - additional section of ileocecal valve

B11 - five lymph node candidates

B12 - five lymph node candidates

B13 - five lymph node candidates

B14,B15 - one grossly positive node, bisected

B16 - four lymph node candidates

B17 - two lymph node candidates

Container C:

SITE: "liver, Segment 5"

METHOD: biopsy

MEASURE: 1.0 x 0.8 x 0.4 cm

COMMENT: tan/brown soft tissue mass

BLOCK: C1,

Container D is additionally labeled "hernia sac." It holds three pink/tan soft tissue fragments measuring 2.5 x 1.9 x 0.8 cm in aggregate.

[page 3 of 3]
Block Summary:
D1 - hernia sac
Fibroadipose tissue remains.

Grossing Pathologist:

Light Microscopy:
Light microscopic examination is performed by

Source: NCI Genomic Data Commons file cce01005-aff8-4d50-9eca-263eaf263b3d (TCGA-AY-5543.38444650-4E96-445C-9E40-04DAEFA76834.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).